Somatic mutation profile of tumor specimen ALCH-B0CY-TTP1-A (aliquot ALCH-B0CY-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0CY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 81.5 years (29,774 days).
Specimen ALCH-B0CY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09ac5ec4-9e98-43e5-9443-4a3dfb0d9f06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0CY-NB1-A (Blood Derived Normal), aliquot ALCH-B0CY-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33d98ec3-67c9-425a-82e5-7ab1e1194586

The open-access MAF lists 113 somatic variants for this specimen: 82 protein-altering or splice-affecting, 19 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 19, Nonsense Mutation 5, RNA 5, Frame Shift Del 4, 5'UTR 4, Intron 3, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>G p.R282G | Missense Mutation (SNP) | VAF 42/307 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BRD8 | c.979A>G p.T327A (on ENST00000254900 / NM_139199.2; = p.T400A on NM_006696.4) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1429310900; called by muse, mutect2, varscan2
- CAMTA2 | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1205194737; called by muse, mutect2, varscan2
- COL22A1 | c.3001C>G p.L1001V | Missense Mutation (SNP) | VAF 38/328 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.042); catalogued as COSV57332797; called by muse, mutect2, varscan2
- DCAF12L1 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.036); catalogued as COSV100948215, COSV104427728; called by muse, mutect2
- DPP6 | c.1102C>G p.L368V (on ENST00000377770 / NM_001364500.2; = p.L306V on NM_001936.5) | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs778649445; called by muse, mutect2, varscan2
- FAM171B | c.1536G>C p.K512N | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100488918; called by muse, mutect2
- FAM71B | c.1323del p.S443Vfs*46 | Frame Shift Del (DEL) | VAF 17/149 reads (11%) | catalogued as COSV57230023; called by mutect2, pindel, varscan2
- FCGBP | c.10792C>T p.R3598C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs1419034147; called by muse, mutect2, varscan2
- FRMPD3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs772917423; called by muse, mutect2
- GRIN2A | c.2357-1G>T p.X786_splice | Splice Site (SNP) | VAF 24/211 reads (11%) | catalogued as COSV58044455; called by muse, mutect2, varscan2
- IGHV1-58 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 74/312 reads (24%) | catalogued as rs1213803104; called by muse, mutect2, varscan2
- IGKV1D-8 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as rs766613689; called by muse, mutect2, varscan2
- IL27 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs150815897; called by muse, mutect2, varscan2
- KIF26B | c.2293C>G p.L765V | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1273251742; called by muse, mutect2, varscan2
- MET | c.2856C>A p.F952L | Missense Mutation (SNP) | VAF 136/467 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs1363551867, COSV59259668; called by muse, mutect2, varscan2
- MICAL3 | c.5407G>A p.D1803N | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1472056471, COSV101490813; called by muse, mutect2, varscan2
- MYCBP2 | c.11144G>T p.R3715L (on ENST00000357337; = p.R3753L on NM_015057.5) | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV62018941; called by muse, mutect2
- MYO1F | c.1165G>A p.G389S | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57794717; called by muse, mutect2, varscan2
- NCALD | c.135G>T p.M45I | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV55272279; called by muse, mutect2
- OCA2 | c.2248C>G p.P750A | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV62357767; called by muse, mutect2
- OR6T1 | c.183C>A p.F61L | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as rs944151304; called by muse, mutect2, varscan2
- OTOG | c.5626C>A p.H1876N | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as rs1440154973; called by muse, mutect2, varscan2
- PAPLN | c.1381G>A p.A461T (on ENST00000554301; = p.A434T on NM_173462.4) | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs748616882, COSV53723572; called by muse, mutect2, varscan2
- PCDHB7 | c.1711C>A p.P571T | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.645); catalogued as rs1195859347, COSV99176949; called by muse, mutect2, varscan2
- PDE1C | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs766909296, COSV100374191, COSV58530800; called by muse, mutect2, varscan2
- RAD51 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1428987216, COSV51111007, COSV51112946; called by muse, mutect2
- RASAL2 | c.1317del p.N440Tfs*10 | Frame Shift Del (DEL) | VAF 11/97 reads (11%) | catalogued as COSV62724391; called by mutect2, pindel
- RGS7 | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1463366057, COSV100465610; called by muse, mutect2
- RNF148 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as rs777028409; called by muse, mutect2, varscan2
- RNF213 | c.2841C>A p.F947L | Missense Mutation (SNP) | VAF 30/526 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV100173003; called by muse, mutect2
- RYR2 | c.5494G>A p.G1832S | Missense Mutation (SNP) | VAF 47/411 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs727504983, COSV63679447; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SELL | c.320T>C p.I107T (on ENST00000650983; = p.I94T on NM_000655.5) | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as rs1354731855; called by muse, mutect2, varscan2
- SIGLEC6 | c.608C>A p.T203N | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs374725455; called by muse, mutect2, varscan2
- SPATA7 | c.544A>G p.S182G | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV99247879; called by muse, mutect2
- TRIM51 | c.935G>C p.G312A | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.354); catalogued as rs1417191998, COSV99792134; called by muse, mutect2, varscan2
- ZEB2 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 20/206 reads (10%) | catalogued as COSV57956456; called by muse, mutect2
- ADAM12 | c.367G>T p.G123* | Nonsense Mutation (SNP) | VAF 18/152 reads (12%) | called by muse, mutect2, varscan2
- AGRN | c.3091C>T p.P1031S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ARMCX6 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 17/256 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); called by muse, mutect2
- ASIC2 | c.1284A>C p.L428F | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C15orf39 | c.596C>A p.S199Y | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- C1orf68 | c.396C>G p.C132W | Missense Mutation (SNP) | VAF 23/260 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.442); called by muse, mutect2
- C1orf68 | c.398A>C p.Y133S | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); called by muse, mutect2
- CACNA1F | c.2540A>T p.E847V | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- CASKIN1 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CATSPERE | c.1760C>G p.A587G | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2
- CCDC166 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2
- CDH23 | c.4685T>A p.V1562D | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.268); called by muse, mutect2
- CMTM4 | c.608T>C p.I203T | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); called by muse, mutect2
- COL6A5 | c.5599G>C p.V1867L (on ENST00000312481; = p.V1863L on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/486 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2
- CPED1 | c.3068A>C p.K1023T | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, varscan2
- CTCF | c.493C>G p.Q165E | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.857); called by muse, mutect2
- DCX | c.282C>A p.N94K | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- DNAH9 | c.7222del p.T2408Qfs*60 | Frame Shift Del (DEL) | VAF 21/92 reads (23%) | called by mutect2, pindel, varscan2
- DUSP9 | c.890C>A p.S297Y | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GCN1 | c.7773del p.K2591Nfs*4 | Frame Shift Del (DEL) | VAF 36/323 reads (11%) | called by mutect2, pindel, varscan2
- GOLIM4 | c.1515C>T p.A505= | Splice Region (SNP) | VAF 9/218 reads (4%) | called by muse, mutect2
- HHLA1 | c.1501A>T p.K501* | Nonsense Mutation (SNP) | VAF 16/166 reads (10%) | called by muse, mutect2, varscan2
- HSPA8 | c.854A>T p.D285V | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- IL12A | c.743G>T p.S248I | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KCTD3 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1549L | c.1999A>T p.S667C (on ENST00000321505; = p.S964C on NM_012194.3) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- OTUD5 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB14 | c.2315C>A p.P772H | Missense Mutation (SNP) | VAF 19/231 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.583); called by muse, mutect2
- PCDHGB1 | c.1250C>A p.T417K | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLEKHG4B | c.2839C>T p.L947F (on ENST00000283426; = p.L1303F on NM_052909.5) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- POSTN | c.2374G>C p.E792Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- R3HDM2 | c.2714G>T p.G905V | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- R3HDM2 | c.2713G>T p.G905W | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RGPD3 | c.3872G>T p.G1291V | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RHNO1 | c.397A>T p.S133C | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLIT2 | c.2747T>C p.L916P | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.52); called by muse, mutect2
- TBC1D1 | c.3083G>A p.S1028N | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TBC1D21 | c.413T>C p.V138A | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TSPAN7 | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- URB2 | c.2930C>A p.S977* | Nonsense Mutation (SNP) | VAF 22/175 reads (13%) | called by muse, mutect2, varscan2
- VIRMA | c.3977T>C p.I1326T | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR19 | c.2527A>G p.K843E | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.185); called by muse, mutect2
- XKR9 | c.404G>A p.R135K | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.621); called by muse, mutect2
- ZIC1 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF362 | c.1229C>T p.S410F | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); called by muse, mutect2
- ADAMTS2 | c.1068C>T p.H356= | Silent (SNP) | VAF 38/220 reads (17%) | catalogued as rs372834434; called by muse, mutect2, varscan2
- AP2A2 | c.690C>G p.V230= | Silent (SNP) | VAF 16/268 reads (6%) | catalogued as COSV59958338; called by muse, mutect2
- BCL2L14 | c.879C>A p.V293= | Silent (SNP) | VAF 28/217 reads (13%) | called by muse, mutect2, varscan2
- BHLHE41 | c.1446C>T p.P482= | Silent (SNP) | VAF 26/251 reads (10%) | catalogued as rs1321209048; called by muse, mutect2, varscan2
- COL22A1 | c.3969G>A p.R1323= | Silent (SNP) | VAF 41/313 reads (13%) | called by muse, mutect2, varscan2
- COLGALT1 | c.360A>T p.A120= | Silent (SNP) | VAF 11/111 reads (10%) | called by muse, mutect2, varscan2
- ERO1B | c.993A>T p.G331= | Silent (SNP) | VAF 22/193 reads (11%) | called by muse, mutect2, varscan2
- FN3KRP | c.777T>C p.F259= | Silent (SNP) | VAF 26/224 reads (12%) | called by muse, mutect2
- KLHL17 | c.186C>A p.R62= | Silent (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2, varscan2
- MICALL1 | c.1146G>A p.K382= | Silent (SNP) | VAF 26/98 reads (27%) | called by muse, mutect2, varscan2
- MRC1 | c.2478G>A p.A826= | Silent (SNP) | VAF 35/267 reads (13%) | catalogued as rs1331086404; called by muse, mutect2, varscan2
- OR5H1 | c.141T>A p.A47= | Silent (SNP) | VAF 29/178 reads (16%) | called by muse, mutect2, varscan2
- OR8B8 | c.282C>T p.Y94= | Silent (SNP) | VAF 19/159 reads (12%) | catalogued as rs192565858, COSV60145879; called by muse, mutect2, varscan2
- RIMS1 | c.3384A>C p.S1128= | Silent (SNP) | VAF 26/153 reads (17%) | called by muse, mutect2, varscan2
- SAPCD1 | c.387A>G p.P129= (on ENST00000425424; = p.P159= on NM_001039651.1) | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as rs1204008501; called by muse, mutect2, varscan2
- SIGLEC6 | c.750C>T p.S250= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as rs745563782, COSV58432366; called by muse, mutect2, varscan2
- SIGLEC6 | c.609C>A p.T203= | Silent (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- TMEM108 | c.1647T>C p.Y549= | Silent (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- UBR4 | c.15426G>A p.L5142= | Silent (SNP) | VAF 32/150 reads (21%) | called by muse, mutect2, varscan2
- ABAT | c.-31C>T | 5'UTR (SNP) | VAF 38/277 reads (14%) | catalogued as rs745997771; called by muse, mutect2, varscan2
- AL359195.2 | n.3277C>A | RNA (SNP) | VAF 17/114 reads (15%) | catalogued as rs1435976284; called by muse, mutect2, varscan2
- ANKRD20A5P | n.39G>C | RNA (SNP) | VAF 24/167 reads (14%) | called by muse, mutect2, varscan2
- CSH1 | c.-10C>T | 5'UTR (SNP) | VAF 27/254 reads (11%) | catalogued as rs1209229636; called by muse, mutect2, varscan2
- FLJ42393 | n.758A>G | RNA (SNP) | VAF 20/209 reads (10%) | catalogued as rs1249833968; called by muse, mutect2
- FLYWCH1 | c.1514-749C>T | Intron (SNP) | VAF 15/68 reads (22%) | catalogued as rs781752221; called by muse, mutect2, varscan2
- GAK | c.268-342G>T | Intron (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2, varscan2
- NPIPB1P | n.989G>A | RNA (SNP) | VAF 51/335 reads (15%) | catalogued as rs200480153; called by muse, mutect2, varscan2
- OR2L1P | n.799C>T | RNA (SNP) | VAF 24/141 reads (17%) | catalogued as rs1038433549; called by muse, mutect2, varscan2
- PNP | c.-60C>T | 5'UTR (SNP) | VAF 34/165 reads (21%) | catalogued as rs1335627969; called by muse, mutect2, varscan2
- SFTPB | c.-54G>A | 5'UTR (SNP) | VAF 12/35 reads (34%) | catalogued as rs34024265; called by muse, mutect2
- ST8SIA5 | c.132-16761G>C | Intron (SNP) | VAF 22/248 reads (9%) | called by muse, mutect2
